Somatic mutation profile of tumor specimen 0DDHU3 from CCDI case PBBNLA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, anaplastic; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.2 years (5,917 days).
Specimen 0DDHU3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21103bef-1dc0-4ede-95fe-d38df5d7dff1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDHU4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d7e4774-937a-4386-9caa-458edfd1b332

The open-access MAF lists 12 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZHIP | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 83/95 reads (87%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs782576349; called by muse, mutect2, varscan2
- MRGPRX1 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 90/470 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs757338968, COSV57106021; called by muse, mutect2, varscan2
- PSMD3 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766521376, COSV52856302; called by muse, mutect2
- FNIP2 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 176/458 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF781 | c.356G>T p.C119F | Missense Mutation (SNP) | VAF 128/349 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by mutect2, varscan2
- ARMC3 | c.1224T>C p.S408= | Silent (SNP) | VAF 108/485 reads (22%) | catalogued as rs763481063; called by muse, mutect2, varscan2
- BECN2 | c.471C>T p.D157= | Silent (SNP) | VAF 74/382 reads (19%) | catalogued as rs907220506; called by muse, mutect2, varscan2
- CDH10 | c.384C>T p.R128= | Silent (SNP) | VAF 255/672 reads (38%) | catalogued as rs768905224, COSV52568657, COSV52580692; called by muse, mutect2, varscan2
- RHPN2 | c.9C>T p.D3= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs918884736; called by mutect2, varscan2
- ATP6V1E1 | c.366+50T>C | Intron (SNP) | VAF 47/134 reads (35%) | called by muse, mutect2, varscan2
- GNA12 | c.*27G>A | 3'UTR (SNP) | VAF 42/99 reads (42%) | catalogued as rs369485204; called by muse, mutect2, varscan2
- LAMA2 | c.8075+66A>G | Intron (SNP) | VAF 26/30 reads (87%) | catalogued as rs563490057; called by muse, mutect2, varscan2
